Surgical pathology report (de-identified scan), TCGA case TCGA-49-4488, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-4488-01A (Primary Tumor).

NAL DIAGNOSIS -----

LEFT LUNG, LOWER LOBE (LOBECTOMY): MODERATELY WELL DIFFERENTIATED
ADENOCARCINOMA OF THE LUNG. THE CARCINOMA MEASURES 3 CM IN GREATEST
DIMENSIONS HAS FOCAL BRONCHIOLOALVEOLAR FEATURES, AND CLOSELY
APPROACHES BUT DOES NOT INVOLVE THE PLEURA. SIXTEEN (16) LYMPH NODES
IN ALL MARGINS OF RESECTION ARE NEGATIVE FOR TUMOR.

LYMPH NODE (LEVEL 5, EXCISION): ONE (1) LYMPH NODE NEGATIVE FOR
TUMOR.

LYMPH NODE (LEVEL 7, EXCISION): ONE (1) LYMPH NODE NEGATIVE FOR
TUMOR.

LYMPH NODE (LEVEL 9, EXCISION): ONE (1) LYMPH NODE NEGATIVE FOR
TUMOR.

Source: NCI Genomic Data Commons file 03f8d958-e224-41d3-9d56-ed50a0d82f42 (TCGA-49-4488.1AAE91EF-85C6-49F4-A76A-3F09D5CABCB5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).